Somatic mutation profile of tumor specimen TCGA-BG-A0MS-01A (aliquot TCGA-BG-A0MS-01A-11D-A10B-09) from TCGA case TCGA-BG-A0MS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 53.5 years (19,547 days).
Specimen TCGA-BG-A0MS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c1e4e70-bea6-4623-97e3-f11b4e050278.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MS-10A (Blood Derived Normal), aliquot TCGA-BG-A0MS-10A-02W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f933a04-16f9-4a34-a5cc-8d1369f5f277

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 2, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1611G>T p.M537I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1057519799, COSV60641421, COSV60655080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1729_1734del p.R577_D578del (on ENST00000521381 / NM_181523.3; = p.R307_D308del on NM_181504.4) | In Frame Del (DEL) | VAF 51/137 reads (37%) | hotspot (GDC flag); catalogued as COSV57125999; called by mutect2, pindel, varscan2
- ACOX3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs771356481, COSV62713176; called by muse, mutect2, varscan2
- COL27A1 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769508193, COSV61926814; called by muse, mutect2, varscan2
- DMD | c.8957C>T p.A2986V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs779243391, COSV58895793; called by muse, mutect2, varscan2
- ELAVL3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63647433; called by muse, mutect2, varscan2
- FBN3 | c.3610C>A p.P1204T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54468227; called by muse, mutect2, varscan2
- FRK | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73384141; called by muse, mutect2, varscan2
- H2BW1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs372943452, COSV54221050; called by muse, mutect2
- HNRNPR | c.1018-2A>G p.X340_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV56423332; called by muse, mutect2
- HSP90AA1 | c.1195T>A p.S399T | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53490514; called by muse, mutect2, varscan2
- IRX6 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775606320, COSV51858949; called by muse, mutect2
- KMT2D | c.4383del p.L1462Sfs*44 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as COSV56470650; called by mutect2, varscan2
- L1CAM | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs782132624, CD003713, COSV62829455; called by muse, mutect2, varscan2
- MACF1 | c.12307C>T p.R4103* (on ENST00000372915; = p.R2036* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57135374; called by muse, mutect2, varscan2
- MYOM3 | c.2494C>G p.P832A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as COSV58398117; called by muse, mutect2
- ONECUT2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349085016, COSV72153056; called by muse, mutect2
- PDP1 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52603104; called by muse, mutect2, varscan2
- PTEN | c.619del p.S207Vfs*14 | Frame Shift Del (DEL) | VAF 24/45 reads (53%) | catalogued as COSV64298968, COSV64302640; called by mutect2, pindel, varscan2
- PXDNL | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62494805; called by muse, mutect2, varscan2
- QRICH2 | c.1797_1826del p.A600_G609del | In Frame Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs751379159; called by muse*, mutect2
- RLF | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.223); catalogued as COSV65652715; called by muse, mutect2, varscan2
- SIK3 | c.3119G>A p.R1040K (on ENST00000445177 / NM_001366686.2; = p.R998K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV52620516; called by muse, mutect2, varscan2
- SLITRK2 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as rs1556945144, COSV59427015; called by muse, mutect2
- SLITRK3 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.05); catalogued as rs1187928560, COSV53845526; called by muse, mutect2, varscan2
- TARS1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54311281; called by muse, mutect2, varscan2
- TAS1R2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs111534973; called by muse, mutect2, varscan2
- TFAP2B | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53827020; called by muse, mutect2, varscan2
- TPTE | c.1277G>A p.R426H (on ENST00000618007 / NM_199261.4; = p.R408H on NM_199259.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs374643597; called by muse, mutect2, varscan2
- TRPM6 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs121912624, CM025230, COSV62502510, COSV62518604; called by muse, mutect2, varscan2
- TTC38 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779627944, COSV66843833, COSV66843978; called by muse, mutect2, varscan2
- ZBBX | c.2070T>A p.D690E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV56796884; called by muse, mutect2, varscan2
- ZFP2 | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63726513; called by muse, mutect2, varscan2
- ZNF566 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs144570782, COSV67574349; called by muse, mutect2, varscan2
- DISP1 | c.3217A>G p.I1073V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- PTEN | c.284del p.P95Hfs*4 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.1157dup p.N386Kfs*4 | Frame Shift Ins (INS) | VAF 28/62 reads (45%) | called by mutect2, varscan2
- CDHR1 | c.2478G>A p.P826= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV60560920; called by muse, mutect2, varscan2
- FGFR4 | c.486A>G p.V162= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV52802856; called by muse, mutect2, varscan2
- HNRNPU | c.708T>A p.A236= (on ENST00000283179; = p.A298= on NM_004501.3) | Silent (SNP) | VAF 95/268 reads (35%) | catalogued as COSV51693080; called by muse, mutect2, varscan2
- IRS4 | c.3699C>T p.N1233= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs773769067, COSV64535274; called by muse, mutect2, varscan2
- NEXMIF | c.279T>C p.S93= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV50066487; called by muse, mutect2, varscan2
- PCDHA7 | c.1170G>A p.T390= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV65346327; called by muse, mutect2, varscan2
- TSNAX | c.444T>A p.I148= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV64146904; called by muse, mutect2, varscan2
- ZNF551 | c.1986G>A p.R662= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56594280; called by muse, mutect2, varscan2
- ZNF554 | c.147C>T p.D49= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs769827968, COSV57886643; called by muse, mutect2, varscan2
- CACNA1D | c.1478+343C>T | Intron (SNP) | VAF 26/67 reads (39%) | catalogued as rs370024486; called by muse, mutect2, varscan2
